Gene-level copy-number profile of tumor specimen TCGA-G9-7521-01A from TCGA case TCGA-G9-7521, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 52.6 years (19,216 days).
Specimen TCGA-G9-7521-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.158a4a47-b1c7-4907-8eaf-eb09bca2c6ca.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-G9-7521-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e3b5d829-9cb3-4a44-8836-19d7256fe408

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 838; copy number 2: 7,207; copy number 3: 10,884; copy number 4: 36,085; copy number 5: 1,950; copy number 6: 426; copy number 7: 309; copy number 8: 735; copy number 9: 112; copy number 10: 1,268.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-G9-7521-01A-11D-2259-01): tumor purity 0.42, ploidy 3.9, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,380 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:171,439,526–180,037,053, 112 genes, copy number 9 (within-gene range 5–9) (broad region; genes not listed).
- chr8:63,687,179–64,369,176, 1 gene, copy number 10 (within-gene range 7–10): LINC01414.
- chr8:64,331,927–145,066,685, 1,267 genes, copy number 10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 838. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
